Gene-level copy-number profile of tumor specimen TCGA-BR-4183-01A from TCGA case TCGA-BR-4183, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 55.9 years (20,420 days).
Specimen TCGA-BR-4183-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.8f344547-f451-4dcb-a1aa-e2e2805fb8ba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-4183-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a43c8566-94e9-49a5-a775-b8f9d3c6b27e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,461; copy number 2: 17,992; copy number 3: 23,522; copy number 4: 10,182; copy number 5: 4,767; copy number 6: 472; copy number 7: 245; copy number 8: 182; copy number 9: 134; copy number 10: 329; copy number 11: 6; copy number 12: 148; copy number 13: 29; copy number 14: 70; copy number 15: 62; copy number 16: 52; copy number 17: 60; copy number 18: 1; copy number 22: 30; copy number 28: 5; copy number 31: 2; copy number 34: 1; copy number 50: 6; copy number 52: 2; copy number 57: 20; copy number 59: 3; copy number 62: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-4183-01A-02D-1130-01): tumor purity 0.29, ploidy 2.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:47,115,838–48,023,004, 7 genes (within-gene range 0–1): FP325331.1, Z83836.1, Z82186.1, LINC01644, LINC00898, AL117329.1, AL117329.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,404 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:221,133,865–221,840,717, 9 genes, copy number 7–10: AL445466.1, LINC02817, AL360013.2, AL360013.3, AL360013.1, AL360013.4, DUSP10, LINC01655, RNU6-403P.
- chr1:222,261,833–231,819,244, 265 genes, copy number 10–15 (within-gene range 2–15) (broad region; genes not listed).
- chr1:231,670,635–231,670,750, 1 gene, copy number 10: RNU5A-5P.
- chr1:234,212,606–234,959,989, 30 genes, copy number 9: AL122008.3, AL122008.1, SLC35F3-AS1, AL122008.2, MIR4671, AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1.
- chr1:238,107,736–238,108,567, 1 gene, copy number 11: YWHAQP9.
- chr1:238,268,494–238,268,595, 1 gene, copy number 11: AL356010.1.
- chr1:240,014,348–240,776,824, 18 genes, copy number 7 (within-gene range 3–7): FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8.
- chr2:114,442,299–115,845,780, 6 genes, copy number 7 (within-gene range 3–7): DPP10, DPP10-AS3, DPP10-AS2, AC093610.1, DPP10-AS1, RPSAP23.
- chr3:68,731,766–72,583,535, 53 genes, copy number 14: TAFA4, RNA5SP135, EOGT, AC109587.1, TMF1, MIR3136, UBA3, ARL6IP5, LMOD3, FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2, AC104633.1, AC104633.2, COX6CP6, HMGB1P36, RNU6-281P, FOXP1, AC097634.4, FOXP1-AS1, MIR1284, AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1, EIF4E3, GPR27, PROK2, AC096970.1, RN7SL271P, LINC00877, UBE2Q2P9, AC105265.2, AC105265.3, AC105265.1, CCDC137P, LINC00870, AC112219.2, AC112219.1, AC134508.2, AC134508.1, RYBP, AC104435.2, RNU1-62P, AC104435.1.
- chr3:75,624,275–75,670,156, 1 gene, copy number 15 (within-gene range 2–15): RPL23AP49.
- chr3:75,653,561–78,525,485, 20 genes, copy number 8–15: AGGF1P3, RARRES2P1, FRG2C, DUX4L26, LINC00960, ZNF717, MIR4273, ROBO2, Y_RNA, CAP1P1, RNU6-386P, VDAC1P7, AC133040.1, RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3.
- chr7:53,862,233–55,433,742, 23 genes, copy number 11–62: HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr8:150,584–2,926,689, 57 genes, copy number 12–17: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1.
- chr8:3,373,353–3,426,587, 2 genes, copy number 17: AC026991.1, AC026991.2.
- chr8:6,924,697–15,766,649, 292 genes, copy number 9–22 (broad region; genes not listed).
- chr8:40,153,482–40,172,612, 2 genes, copy number 7: TCIM, AC022733.1.
- chr9:105,656,369–105,851,425, 6 genes, copy number 8: AL158070.2, TAL2, TMEM38B, AL592437.1, DEPDC1P2, SLC25A6P5.
- chr9:123,356,170–125,372,766, 44 genes, copy number 8: CRB2, DENND1A, MIR601, MIR7150, AL445489.1, AL390774.2, AL390774.1, PIGFP2, LHX2, AC006450.3, AC006450.1, AC006450.2, NEK6, AL162724.2, AL162724.1, PSMB7, ADGRD2, NR5A1, AL354979.1, NR6A1, AL669818.1, RN7SL302P, MIR181A2HG, MIR181A2, MIR181B2, AL354928.1, OLFML2A, WDR38, RPL35, ARPC5L, GOLGA1, RNU4-82P, SCAI, FXNP2, PPP6C, PRPS1P2, RPSAP76, RABEPK, HSPA5, AL354710.2, GAPVD1, AL354710.1, RNU6-1020P, AL627223.1.
- chr9:136,881,912–137,168,756, 29 genes, copy number 13 (within-gene range 6–13): TRAF2, MIR4479, AL807752.1, AL807752.5, FBXW5, C8G, LCN12, LINC02692, PTGDS, AL807752.7, LCNL1, PAXX, CLIC3, ABCA2, C9orf139, FUT7, AL807752.6, NPDC1, ENTPD2, AL807752.4, AL807752.2, SAPCD2, AL807752.3, UAP1L1, MAN1B1-DT, MAN1B1, SNORD62, DPP7, GRIN1.
- chr10:8,970,125–14,462,142, 84 genes, copy number 7–59 (within-gene range 5–59) (broad region; genes not listed).
- chr10:56,357,227–70,428,618, 179 genes, copy number 7–50 (within-gene range 4–50) (broad region; genes not listed).
- chr10:75,243,568–75,373,500, 1 gene, copy number 10 (within-gene range 6–10): ZNF503-AS1.
- chr10:75,279,726–75,401,246, 1 gene, copy number 10 (within-gene range 6–10): AC010997.3.
- chr10:75,382,393–75,431,588, 6 genes, copy number 10: SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2.
- chr10:75,450,081–75,743,755, 5 genes, copy number 10: AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1.
- chr10:77,730,766–77,739,015, 2 genes, copy number 52: AL731556.1, AL731556.2.
- chr10:120,759,898–121,975,217, 20 genes, copy number 57 (within-gene range 3–57): WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2.
- chr11:18,863,558–19,176,422, 11 genes, copy number 7 (within-gene range 2–7): MRGPRX7P, AC023078.2, MRGPRX6P, MRGPRX5P, MRGPRX1, AC023078.1, MRGPRX11P, MRGPRX10P, MRGPRX9P, MRGPRX2, ZDHHC13.
- chr11:27,040,725–29,989,328, 39 genes, copy number 7 (within-gene range 2–7): BBOX1, BBOX1-AS1, CCDC34, LGR4, LGR4-AS1, AC100771.1, LIN7C, BDNF-AS, MIR8087, RNA5SP339, AC104563.1, LINC00678, BDNF, AC103796.1, CBX3P1, HSP90AA2P, AC090159.1, KIF18A, MIR610, METTL15, ATP5MGP8, RN7SKP158, AC104978.1, MIR8068, AC013714.1, LINC02758, LINC02742, OR2BH1P, AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58.
- chr11:35,579,430–36,697,867, 25 genes, copy number 7: AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1.
- chr11:43,311,963–46,700,619, 92 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr12:66,767–2,941,138, 73 genes, copy number 7 (broad region; genes not listed).
- chr12:16,989,126–17,167,790, 6 genes, copy number 7: SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40.

Autosomal genes at a single copy (total copy number 1): 1,461. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
